HCMI case HCM-CSHL-0726-C18 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Epithelial Neoplasms, NOS; Primary site: Rectum. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/ea53b476-afdd-4df7-bfbb-c3fac39319f7

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1955; Vital status: Alive.

Diagnoses (2)
1. Small cell carcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8041/3; ICD-10 code: C18.9; Tissue or organ of origin: Rectum, NOS; Site of resection or biopsy: Rectum, NOS; Classification of tumor: primary; Age at diagnosis: 62.5 years (22,840 days); AJCC staging edition: 8th; AJCC clinical stage: Stage I; AJCC pathologic T: T2; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage I; Tumor grade: G2; Metastasis at diagnosis: Metastasis, NOS; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: No; Sites of involvement: Liver.
   Pathology details: Lymphatic invasion present: No; Vascular invasion present: No.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 36 days.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Bevacizumab; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 454 days (1.2 years); Days to treatment end: 544 days (1.5 years).
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil + Leucovorin Calcium + Oxaliplatin; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Regimen or line of therapy: FOLFOX; Days to treatment start: 454 days (1.2 years); Days to treatment end: 544 days (1.5 years).
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil + Irinotecan + Leucovorin Calcium; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Regimen or line of therapy: FOLFIRI; Days to treatment start: 972 days (2.7 years); Days to treatment end: 1,098 days (3.0 years).
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Ramucirumab; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 972 days (2.7 years); Days to treatment end: 1,098 days (3.0 years).
   Treatment given: Treatment type: Radiation, Stereotactic/Gamma Knife/SRS; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 1,050 days (2.9 years); Days to treatment end: 1,050 days (2.9 years).
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Regorafenib; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 1,078 days (3.0 years); Days to treatment end: 1,147 days (3.1 years).
   Recorded as not given: neoadjuvant treatment (type not reported); adjuvant Immunotherapy (Including Vaccines), for residual disease.
2. Adenocarcinoma, metastatic, NOS: ICD-O-3 morphology code: 8140/6; ICD-10 code: C78.7; Tissue or organ of origin: Rectum, NOS; Site of resection or biopsy: Liver; Classification of tumor: metastasis; Age at diagnosis: 63.6 years (23,226 days); Days to diagnosis: 386 days (1.1 years).
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Bevacizumab; Treatment intent type: Maintenance Therapy; Days to treatment start: 453 days (1.2 years); Days to treatment end: 544 days (1.5 years); Treatment outcome: Treatment Ongoing.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Oxaliplatin; Treatment intent type: Maintenance Therapy; Regimen or line of therapy: FOLFOX; Days to treatment start: 453 days (1.2 years); Days to treatment end: 544 days (1.5 years); Treatment outcome: Treatment Ongoing.

Follow-up (3 entries)
- Days to follow up: 0 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Liver; Days to progression: 0 days.
- Days to follow up: 1,147 days (3.1 years); Disease response: Progressive Disease; Progression or recurrence: Yes.
- Follow-up contact recording only the day: day 728.

Molecular and laboratory tests
- CEA: 2 ng/mL.
- MLH1 (IHC): Positive.
- MLH1 methylation: Equivocal.
- MSH2 (IHC): Positive.
- MSH6 (IHC): Positive.
- PMS2 (IHC): Positive.
- Test (Microsatellite Analysis): Negative.
- Test: Negative; Mismatch repair mutation: Yes.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Risk factors: Cancer.
- Timepoint category: Initial Diagnosis; Weight: 75 kg; Height: 172 cm; BMI: 25.4.

Exposures
- Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs.

Family history
- Relative with cancer history: yes; Relationship type: First Degree Relative, NOS; Relationship primary diagnosis: Cancer.

Biospecimens (2 samples)
- Sample HCM-CSHL-0726-C18-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Whole Blood; Preservation method: Frozen.
- Sample HCM-CSHL-0726-C18-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 5.
